Surgical pathology report (de-identified scan), TCGA case TCGA-06-0176, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0176-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL, EXCISION: GLIOBLASTOMA MULTIFORME.

SEE COMMENT.

ADDENDUM REPORT:

B. BRAIN, RIGHT FRONTAL LOBE, EXCISION: GIANT CELL GLIOBLASTOMA.
MIB-1 PROLIFERATION INDEX: 20%.

SEE COMMENT.

Operation/Specimen: UPDATED REPORT - Brain.

Clinical History and Pre-Op Dx: [REDACTED] with [REDACTED] cm contrast enhancing mass in right frontal lobe.

GROSS PATHOLOGY: A. Received fresh, several fragments, 1.2 cm across in aggregate. Soft, reddish-brown. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, smears: Malignant neoplasm, glioblastoma multiforme.

COMMENT: The neoplasm is a neoplastic proliferation of astrocytes with prominent nuclear anaplasia, frequent mitotic figures, microvascular cellular proliferation, and extensive areas of necrosis, i.e. glioblastoma multiforme. There are numerous giant cells throughout. Special stains to confirm this diagnosis are being requested and an addendum report will follow.

ADDENDUM REPORT

B.

SPECIMEN: Right frontal lobe brain tumor.

FIXATIVE: None.

GENERAL: Two irregular, partially fragmented, pale tan to maroon soft hemorrhagic tissue fragments, 2.0 x 1.5 x 1.0 cm., and 3.0 x 2.0 x 1.2 cm.

SECTIONS: Representative sections 3 - smaller fragments; 4-6 - representative largest fragment.

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, CD34, p53, cytokeratin, CK7 and MIB-1 were performed on sections from block #1.

[page 2 of 2]
[REDACTED]

The neoplastic cells are immunoreactive with GFAP. Slight non-^{TCGA-06-0176} reactivity with CK is observed focally (CK positive, CK7 negative). A majority of cells (>75%) overexpress the p53 protein. The CD34 demonstrates rich vascularity. With the MIB-1, a proliferation index of 25% is seen throughout.

COMMENT: In part B there is a neoplasm histologically similar to that one in specimen A. The neoplasm is rather circumscribed, has extensive areas of necrosis, and is extending in to the leptomeninges.

MICROSCOPIC: 6 blocks, 6 slides, 6 immunostains.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 8b437f42-6239-46dd-a22c-910cf958b78c (TCGA-06-0176.4ACF6767-5EFB-4BFD-8F5D-EDEF05709C9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).